Somatic mutation profile of tumor specimen MBCProject_0209_T1_WES (aliquot MBCProject_0209_T1_WES_1) from CMI case MBCProject_0209, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 53.3 years (19,456 days).
Specimen MBCProject_0209_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 514320e8-c3da-4a50-9cff-720f95e1b79e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_0209_SALIVA (Saliva), aliquot MBCProject_0209_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d20ba0ff-0b0d-489e-a44b-2655dd5a1cd5

The open-access MAF lists 104 somatic variants for this specimen: 69 protein-altering or splice-affecting, 24 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 64, Silent 24, Intron 8, Nonsense Mutation 4, RNA 3, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.910C>T p.R304* | Nonsense Mutation (SNP) | VAF 38/139 reads (27%) | catalogued as rs786203950, CM087437, CS983483, COSV62192041, COSV62210573; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ARHGAP36 | c.490C>T p.R164C | Missense Mutation (SNP) | VAF 79/323 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); catalogued as rs1274306403, COSV52268253; called by muse, mutect2, varscan2
- ARMC6 | c.316C>T p.R106C (on ENST00000392336; = p.R81C on NM_033415.4) | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs771359865, COSV99523051; called by muse, mutect2
- ARRB2 | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 29/221 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.831); catalogued as rs771693958, COSV99036395; called by muse, mutect2, varscan2
- BCL11B | c.820G>A p.V274M (on ENST00000357195 / NM_001282237.2; = p.V203M on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.864); catalogued as rs961324878; called by muse, mutect2, varscan2
- CAPN12 | c.1600A>G p.I534V | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as rs1489623749; called by muse, varscan2
- CNTRL | c.5297G>A p.R1766Q | Missense Mutation (SNP) | VAF 59/399 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs536241829; called by muse, mutect2, varscan2
- COL27A1 | c.3573G>T p.E1191D | Missense Mutation (SNP) | VAF 8/166 reads (5%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.992); catalogued as COSV61929632; called by muse, mutect2
- CXorf65 | c.238C>T p.R80C | Missense Mutation (SNP) | VAF 9/110 reads (8%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.987); catalogued as rs963337813, COSV52147220; called by muse, mutect2
- DENND2C | c.2048G>A p.R683Q (on ENST00000393274 / NM_001256404.2; = p.R626Q on NM_198459.4) | Missense Mutation (SNP) | VAF 18/173 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0.107); catalogued as rs778828074; called by muse, mutect2
- H3C6 | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 74/371 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.323); catalogued as COSV64519400, COSV64519670; called by muse, mutect2, varscan2
- HAVCR2 | c.65C>T p.S22L | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV100324997; called by muse, mutect2, varscan2
- HUWE1 | c.12212G>C p.R4071P | Missense Mutation (SNP) | VAF 26/225 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99474725; called by muse, mutect2, varscan2
- IMPG1 | c.1535G>A p.G512D | Missense Mutation (SNP) | VAF 35/179 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.033); catalogued as rs767649818; called by muse, mutect2, varscan2
- KBTBD13 | c.1049G>A p.R350H | Missense Mutation (SNP) | VAF 28/269 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.534); catalogued as COSV71351393; called by muse, mutect2
- KBTBD3 | c.1076G>A p.R359Q | Missense Mutation (SNP) | VAF 16/196 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs144374781; called by muse, mutect2
- KCNA1 | c.626C>T p.T209M | Missense Mutation (SNP) | VAF 9/123 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.736); catalogued as rs1565433235, COSV66836415; called by muse, mutect2
- KMT2A | c.4961C>T p.S1654F | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV63291890; called by muse, mutect2, varscan2
- LAMA5 | c.6773G>C p.R2258P | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.013); catalogued as COSV53363735; called by muse, mutect2, varscan2
- LNX2 | c.1719C>A p.S573R | Missense Mutation (SNP) | VAF 52/325 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.133); catalogued as COSV60334049; called by muse, mutect2, varscan2
- MXRA5 | c.5894G>C p.G1965A | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54242754; called by muse, mutect2
- NRP1 | c.1967C>T p.S656F | Missense Mutation (SNP) | VAF 18/163 reads (11%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.975); catalogued as COSV55160899; called by muse, mutect2, varscan2
- NYNRIN | c.1537G>A p.A513T | Missense Mutation (SNP) | VAF 21/174 reads (12%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as rs748667976, COSV101230554; called by muse, mutect2, varscan2
- OR5D13 | c.82C>G p.P28A | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.323); catalogued as COSV62332770; called by muse, mutect2
- OR6C4 | c.185G>A p.R62Q | Missense Mutation (SNP) | VAF 13/148 reads (9%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.02); catalogued as rs762612300, COSV67793177; called by muse, mutect2
- PCDH17 | c.2909G>A p.R970H | Missense Mutation (SNP) | VAF 18/224 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.861); catalogued as rs149002900, COSV64975035; called by muse, mutect2
- PLCB1 | c.2974C>A p.Q992K | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as COSV62069372; called by muse, mutect2, varscan2
- PRMT3 | c.862G>T p.E288* | Nonsense Mutation (SNP) | VAF 18/210 reads (9%) | catalogued as COSV58178694; called by muse, mutect2
- PROSER2 | c.1139G>A p.R380H | Missense Mutation (SNP) | VAF 12/117 reads (10%) | SIFT tolerated (0.45); PolyPhen benign (0.01); catalogued as rs1222313481, COSV53206695; called by muse, mutect2, varscan2
- PRPF6 | c.686G>C p.G229A | Missense Mutation (SNP) | VAF 24/342 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as COSV99412155; called by muse, mutect2
- TBX5 | c.7G>A p.D3N | Missense Mutation (SNP) | VAF 26/339 reads (8%) | SIFT tolerated (0.53); PolyPhen benign (0.033); catalogued as rs1565943407; called by muse, mutect2
- TRPV5 | c.1042G>A p.V348I | Missense Mutation (SNP) | VAF 53/409 reads (13%) | SIFT tolerated (0.47); PolyPhen benign (0.02); catalogued as rs779621537, COSV54685314; called by muse, mutect2, varscan2
- UBTFL1 | c.76C>T p.R26C | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs749803628, COSV73297938; called by muse, mutect2, varscan2
- USH2A | c.13823G>A p.R4608Q | Missense Mutation (SNP) | VAF 23/122 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0.04); catalogued as rs776471973, COSV56333866, COSV56354805; called by muse, mutect2, varscan2
- AGPS | c.1772C>T p.P591L | Missense Mutation (SNP) | VAF 21/272 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- AKIRIN1 | c.188C>T p.P63L | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2
- AMMECR1 | c.670G>C p.E224Q | Missense Mutation (SNP) | VAF 21/226 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- AURKB | c.15G>C p.E5D | Missense Mutation (SNP) | VAF 21/127 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- BAAT | c.612A>T p.E204D | Missense Mutation (SNP) | VAF 63/270 reads (23%) | SIFT tolerated (0.59); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- C20orf27 | c.102G>C p.E34D (on ENST00000379772 / NM_001258429.2; = p.E59D on NM_001039140.3) | Missense Mutation (SNP) | VAF 17/184 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- CCDC39 | c.1135G>T p.D379Y | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); called by muse, mutect2
- CLEC6A | c.216G>C p.K72N | Missense Mutation (SNP) | VAF 41/145 reads (28%) | SIFT tolerated (0.47); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- DCUN1D2 | c.707G>A p.W236* | Nonsense Mutation (SNP) | VAF 9/128 reads (7%) | called by muse, mutect2
- ERAL1 | c.1214G>C p.G405A | Missense Mutation (SNP) | VAF 38/413 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FAM171A1 | c.884C>T p.T295I | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT tolerated (0.69); PolyPhen benign (0.287); called by muse, mutect2
- FANCM | c.3202G>A p.D1068N | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT tolerated (0.46); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FOCAD | c.2258C>T p.S753L | Missense Mutation (SNP) | VAF 28/188 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- IL20 | c.125T>A p.I42K | Missense Mutation (SNP) | VAF 20/238 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); called by muse, mutect2
- INA | c.818A>G p.E273G | Missense Mutation (SNP) | VAF 27/165 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IQCN | c.992C>T p.P331L | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- KIAA1109 | c.120G>C p.W40C | Missense Mutation (SNP) | VAF 31/238 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- KSR1 | c.1710C>G p.I570M (on ENST00000644974 / NM_001367810.1; = p.I455M on NM_014238.2) | Missense Mutation (SNP) | VAF 28/516 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); called by muse, mutect2
- MAP3K13 | c.91C>T p.L31F | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- MDM4 | c.1001G>T p.C334F | Missense Mutation (SNP) | VAF 24/207 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- MYH2 | c.5158C>G p.Q1720E | Missense Mutation (SNP) | VAF 38/337 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NRAP | c.4845C>G p.S1615R (on ENST00000359988 / NM_001322945.2; = p.S1580R on NM_006175.4) | Missense Mutation (SNP) | VAF 30/378 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- OR10A4 | c.885T>A p.N295K | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.323); called by muse, mutect2, varscan2
- PKNOX1 | c.20T>C p.L7S | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.084); called by muse, mutect2
- RIN2 | c.1107C>A p.H369Q (on ENST00000255006 / NM_001242581.1; = p.H320Q on NM_018993.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 89/410 reads (22%) | SIFT tolerated (0.64); PolyPhen benign (0.001); called by muse, varscan2
- SUPT20HL1 | c.1966C>G p.P656A | Missense Mutation (SNP) | VAF 20/204 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- TLN1 | c.91A>G p.I31V | Missense Mutation (SNP) | VAF 37/165 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TRAPPC9 | c.1754G>T p.R585L | Missense Mutation (SNP) | VAF 39/366 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- TRBV6-1 | c.211G>T p.E71* | Nonsense Mutation (SNP) | VAF 34/217 reads (16%) | called by muse, mutect2, varscan2
- UBR4 | c.8786G>A p.G2929E | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2
- VIRMA | c.814G>C p.D272H | Missense Mutation (SNP) | VAF 32/222 reads (14%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.452); called by muse, varscan2
- VIRMA | c.748G>A p.E250K | Missense Mutation (SNP) | VAF 38/303 reads (13%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.015); called by muse, varscan2
- WDFY3 | c.7198_7199del p.T2400* | Frame Shift Del (DEL) | VAF 16/150 reads (11%) | called by mutect2, pindel, varscan2
- WSB1 | c.910A>G p.I304V | Missense Mutation (SNP) | VAF 362/488 reads (74%) | SIFT tolerated (0.82); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZMYM2 | c.596A>T p.D199V | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- ABCE1 | c.1566C>T p.F522= | Silent (SNP) | VAF 21/179 reads (12%) | called by muse, mutect2, varscan2
- ADAM10 | c.1836T>C p.S612= | Silent (SNP) | VAF 75/262 reads (29%) | called by muse, mutect2, varscan2
- ADAM12 | c.1266C>T p.F422= | Silent (SNP) | VAF 22/292 reads (8%) | catalogued as rs973553905, COSV100900603; called by muse, mutect2
- ARFGAP2 | c.81C>T p.F27= | Silent (SNP) | VAF 48/172 reads (28%) | catalogued as COSV54066053; called by muse, mutect2, varscan2
- BTBD11 | c.2904G>C p.V968= (on ENST00000280758 / NM_001018072.2; = p.V505= on NM_001017523.2) | Silent (SNP) | VAF 32/302 reads (11%) | called by muse, mutect2
- CD247 | c.27G>A p.A9= | Silent (SNP) | VAF 99/495 reads (20%) | catalogued as rs757294201, COSV100758282; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DOCK8 | c.3204G>A p.V1068= | Silent (SNP) | VAF 23/262 reads (9%) | called by muse, mutect2
- ELFN2 | c.1035C>T p.I345= | Silent (SNP) | VAF 10/84 reads (12%) | catalogued as rs777862333, COSV101297503; called by muse, mutect2, varscan2
- GPD1 | c.735C>T p.G245= | Silent (SNP) | VAF 106/453 reads (23%) | called by muse, mutect2, varscan2
- IRS4 | c.1158C>T p.I386= | Silent (SNP) | VAF 29/262 reads (11%) | catalogued as rs772063061, COSV64533876, COSV64536579; called by muse, mutect2, varscan2
- KANK4 | c.2844C>T p.L948= | Silent (SNP) | VAF 60/168 reads (36%) | catalogued as rs1284996064, COSV100443338; called by muse, mutect2, varscan2
- KCNF1 | c.750C>T p.F250= | Silent (SNP) | VAF 17/78 reads (22%) | catalogued as rs1383666681, COSV54462004; called by muse, mutect2, varscan2
- LETMD1 | c.879G>T p.L293= | Silent (SNP) | VAF 28/232 reads (12%) | called by muse, mutect2, varscan2
- MAP2 | c.1425C>A p.T475= | Silent (SNP) | VAF 6/72 reads (8%) | catalogued as COSV52314299; called by muse, mutect2
- MYO7B | c.1035C>T p.D345= | Silent (SNP) | VAF 18/212 reads (8%) | catalogued as rs764043935, COSV67345136, COSV67349655; called by muse, mutect2
- NDUFC1 | c.132T>A p.V44= | Silent (SNP) | VAF 19/290 reads (7%) | called by muse, mutect2
- PLXNB3 | c.4479G>A p.V1493= | Silent (SNP) | VAF 12/111 reads (11%) | catalogued as rs1431437787; called by muse, mutect2, varscan2
- PNPLA3 | c.1152G>A p.L384= | Silent (SNP) | VAF 14/122 reads (11%) | catalogued as rs773268264; called by muse, mutect2, varscan2
- PRSS1 | c.360C>T p.N120= | Silent (SNP) | VAF 43/267 reads (16%) | catalogued as rs606231348; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- PUS1 | c.627C>G p.A209= | Silent (SNP) | VAF 16/244 reads (7%) | catalogued as rs1011916350; called by muse, mutect2
- TRIM42 | c.993C>T p.S331= | Silent (SNP) | VAF 18/192 reads (9%) | catalogued as rs778063412, COSV99647922; called by muse, mutect2
- UNKL | c.1131C>T p.S377= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as rs1454465563; called by muse, mutect2, varscan2
- ZNF337 | c.1605G>A p.Q535= | Silent (SNP) | VAF 19/183 reads (10%) | called by muse, mutect2, varscan2
- ZNF831 | c.1266C>G p.A422= | Silent (SNP) | VAF 5/36 reads (14%) | called by muse, mutect2, varscan2
- ANGEL1 | c.1688+39C>G | Intron (SNP) | VAF 23/196 reads (12%) | called by muse, mutect2, varscan2
- BDNF | c.-21-15695G>A | Intron (SNP) | VAF 18/77 reads (23%) | called by muse, mutect2, varscan2
- EDN3 | c.52+10C>T | Intron (SNP) | VAF 21/170 reads (12%) | catalogued as rs1201133308; called by muse, mutect2, varscan2
- NUP58 | c.711-13G>T | Intron (SNP) | VAF 11/154 reads (7%) | called by muse, mutect2
- OSGIN1 | n.985C>G | RNA (SNP) | VAF 12/140 reads (9%) | called by muse, mutect2
- PLEC | c.524-672C>G | Intron (SNP) | VAF 28/274 reads (10%) | called by muse, varscan2
- PLEKHM1P1 | n.867G>A | RNA (SNP) | VAF 15/309 reads (5%) | catalogued as rs1441812009; called by muse, mutect2
- SLC26A4 | c.1263+1756C>T | Intron (SNP) | VAF 28/256 reads (11%) | catalogued as rs1017915207; called by muse, mutect2
- SLC27A1 | c.1206+97C>G | Intron (SNP) | VAF 10/156 reads (6%) | called by muse, mutect2
- SMPD4BP | n.1465C>G | RNA (SNP) | VAF 9/76 reads (12%) | called by muse, mutect2, varscan2
- ZSCAN32 | c.839-787G>A | Intron (SNP) | VAF 22/202 reads (11%) | called by muse, mutect2, varscan2
